Surgical pathology report (de-identified scan), TCGA case TCGA-19-5947, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-5947-01A (Primary Tumor).

SURGICAL PATHOLOGY REPORT

TCGA-19-5947

FINAL DIAGNOSIS

A-C. LEFT FRONTAL LOBE OF BRAIN, TUMOR, BIOPSIES AND REMOVAL:
-- GLIOBLASTOMA MULTIFORME (WHO GRADE IV) DEMONSTRATING PROMINENT SPINDLE CELL DIFFERENTIATION ("GLIOSARCOMA").

Electronically Signed Out By [REDACTED]

By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A. Microscopic: Glioblastoma.

Senior pathologist: [REDACTED]

Clinical History:

left frontal neoplasm

Specimens Submitted As:

A: LEFT FRONTAL NEOPLASM

B: CUSA ASPIRATE

C: LEFT FRONTAL TUMOR

Gross Description:

A. Received fresh for intraoperative evaluation labeled with the patient's name, hospital number and "left frontal neoplasm" are multiple pink-tan soft tissue fragments, 2.5 x 1 x 0.1 cm in aggregate. The representative section of the specimen is submitted for intraoperative frozen consultation. The entire specimen is submitted in one cassette.

B: Received in formalin, labeled patient's name and number, is a sock containing multiple irregular, pale tan, soft to rubbery tissue fragments measuring in aggregate 2.0 x 1.2 x 0.2 cm. Submitted in toto in one cassette.

C: Received in formalin, labeled with the patient's name and number, are multiple irregular, opaque white to tan, soft, cerebriform tissue fragments measuring in aggregate 4.5 x 4.2 x 0.8 cm. Submitted entirely in three cassettes.

Source: NCI Genomic Data Commons file 205123c8-a454-4667-86f4-1ede5ecd2cc5 (TCGA-19-5947.204505D4-D58C-4187-8632-A900C41CDC99.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).